Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UR-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1- "Biopsy of uterine cervix":

Mucinous adenocarcinoma of endocervical type.

ICD O-3

Adenocarcinoma, mucinous endocervical
Type 8482/3

Site: Cervix NOS C539

JW 3/7/14

Source: NCI Genomic Data Commons file c6ca01ac-89e9-4e8d-95f1-1ea504dd5822 (TCGA-VS-A9UR.BD8A6A1F-9210-4A69-AB09-EDCFC5F28482.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).